Somatic mutation profile of tumor specimen TCGA-CN-4726-01A (aliquot TCGA-CN-4726-01A-01D-1434-08) from TCGA case TCGA-CN-4726, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cheek mucosa; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 69.0 years (25,194 days).
Specimen TCGA-CN-4726-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c5dcdb61-b6e7-41ff-88f2-73c8e2bb739c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-4726-10A (Blood Derived Normal), aliquot TCGA-CN-4726-10A-01D-1434-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5fd869c5-310b-4b57-9987-47fc505b527f

The open-access MAF lists 69 somatic variants for this specimen: 52 protein-altering or splice-affecting, 17 silent.
By variant classification: Missense Mutation 42, Silent 17, Nonsense Mutation 3, Frame Shift Del 3, Splice Site 2, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.375+2T>A p.X125_splice | Splice Site (SNP) | VAF 63/163 reads (39%) | hotspot (GDC flag); catalogued as rs1555526469, CS147127, COSV52663814, COSV52664353, COSV52730362; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AAAS | c.11T>G p.L4R | Missense Mutation (SNP) | VAF 112/388 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99266814; called by muse, mutect2, varscan2
- ABCD2 | c.1169C>A p.T390N | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV58054568; called by muse, mutect2
- ADCY8 | c.1424G>A p.R475H | Missense Mutation (SNP) | VAF 26/161 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs761354664, COSV53897119, COSV53912768; called by muse, mutect2, varscan2
- ADGRV1 | c.3161C>T p.P1054L | Missense Mutation (SNP) | VAF 44/191 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.255); catalogued as COSV101315513; called by muse, mutect2, varscan2
- APLF | c.404A>G p.N135S | Missense Mutation (SNP) | VAF 60/200 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.162); catalogued as COSV100376378; called by muse, mutect2, varscan2
- ARHGAP36 | c.133C>G p.R45G | Missense Mutation (SNP) | VAF 86/247 reads (35%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.127); catalogued as COSV99357264, COSV99358367; called by muse, mutect2, varscan2
- C14orf93 | c.1001T>C p.I334T | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.985); catalogued as COSV100136599; called by muse, mutect2, varscan2
- CABLES1 | c.1761C>T p.D587= (on ENST00000256925 / NM_001100619.2; = p.D322= on NM_138375.2) | Splice Region (SNP) | VAF 19/83 reads (23%) | catalogued as rs1404633687, COSV56935516; called by muse, mutect2, varscan2
- CAPRIN2 | c.3061T>G p.L1021V | Missense Mutation (SNP) | VAF 37/173 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV99195417; called by muse, mutect2, varscan2
- CCDC77 | c.558G>C p.Q186H | Missense Mutation (SNP) | VAF 70/354 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as COSV99519646; called by muse, mutect2, varscan2
- CLUAP1 | c.74A>G p.E25G | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as rs528317873, COSV100489493; called by muse, mutect2, varscan2
- CMYA5 | c.7526A>T p.K2509I | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as COSV101483845; called by muse, mutect2, varscan2
- CYP46A1 | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 46/189 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766472276, COSV99952453; called by muse, mutect2, varscan2
- DHX9 | c.982G>A p.G328S | Missense Mutation (SNP) | VAF 51/189 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.083); catalogued as rs1253180948, COSV100841242; called by muse, mutect2, varscan2
- EPHA1 | c.2790C>A p.Y930* | Nonsense Mutation (SNP) | VAF 18/70 reads (26%) | catalogued as COSV99313516; called by muse, mutect2, varscan2
- EPHB1 | c.1757G>T p.R586L | Missense Mutation (SNP) | VAF 98/573 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV101212708, COSV67657416; called by muse, mutect2, varscan2
- GCAT | c.992G>A p.R331H | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs750055272, COSV99030606; called by muse, mutect2, varscan2
- GPR179 | c.4015C>T p.Q1339* (on ENST00000621958; = p.Q1338* on NM_001004334.4) | Nonsense Mutation (SNP) | VAF 39/177 reads (22%) | catalogued as rs774716548; called by muse, mutect2, varscan2
- GRID2 | c.939G>T p.K313N | Missense Mutation (SNP) | VAF 58/258 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.386); catalogued as COSV56270352, COSV99937482; called by muse, mutect2, varscan2
- IFT80 | c.1045G>T p.V349F | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100424387, COSV100424854; called by muse, mutect2, varscan2
- IFT88 | c.1897G>A p.E633K (on ENST00000319980 / NM_001318493.2; = p.E624K on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/243 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.516); catalogued as COSV100179450; called by muse, mutect2, varscan2
- KCNQ5 | c.1664C>A p.A555D | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100571323; called by muse, mutect2, varscan2
- KIF27 | c.2815C>T p.R939C | Missense Mutation (SNP) | VAF 23/198 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs3199677; called by muse, mutect2, varscan2
- LRIF1 | c.169C>G p.P57A | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100870796; called by muse, mutect2, varscan2
- MAF | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100391650; called by muse, varscan2
- MRPS10 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.003); catalogued as rs548348475, COSV99273495; called by muse, mutect2
- MSH4 | c.2799G>T p.K933N | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs1374950750, COSV54197061, COSV99590673; called by muse, mutect2, varscan2
- NOTCH2 | c.1445G>C p.C482S | Missense Mutation (SNP) | VAF 98/385 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56689798, COSV99862809; called by muse, mutect2, varscan2
- NR3C2 | c.614G>T p.C205F | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.854); catalogued as COSV100678701; called by muse, mutect2, varscan2
- OTOGL | c.5731C>A p.P1911T (on ENST00000547103; = p.P1902T on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 82/304 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.068); catalogued as COSV100086721; called by muse, mutect2, varscan2
- PCDHA13 | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 83/328 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.441); catalogued as COSV56503062; called by muse, mutect2, varscan2
- PTK2 | c.593+2T>C p.X198_splice | Splice Site (SNP) | VAF 30/160 reads (19%) | catalogued as COSV100569415; called by muse, varscan2
- RC3H1 | c.1477C>A p.L493M | Missense Mutation (SNP) | VAF 68/234 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.905); catalogued as COSV51217943, COSV99281055; called by muse, mutect2, varscan2
- RLF | c.653G>A p.R218Q | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV65650495; called by muse, mutect2, varscan2
- SCAI | c.1487G>A p.R496H (on ENST00000336505 / NM_001144877.3; = p.R519H on NM_173690.5) | Missense Mutation (SNP) | VAF 57/226 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.71); catalogued as rs371655620; called by muse, mutect2, varscan2
- SLC23A1 | c.980C>T p.A327V | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV100811877; called by muse, mutect2, varscan2
- SLU7 | c.1526G>A p.R509Q | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs376066344; called by muse, mutect2, varscan2
- SPTB | c.1558C>T p.R520W | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101071978; called by muse, mutect2, varscan2
- TBC1D20 | c.1078A>T p.T360S | Missense Mutation (SNP) | VAF 101/366 reads (28%) | SIFT tolerated (0.6); PolyPhen benign (0.006); catalogued as COSV100830436; called by muse, mutect2, varscan2
- TBC1D31 | c.2864G>A p.R955H | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs766203135, COSV54864513; called by muse, mutect2, varscan2
- TBXAS1 | c.449A>T p.E150V | Missense Mutation (SNP) | VAF 101/413 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV99694831; called by muse, mutect2, varscan2
- TMEM63B | c.1495G>T p.A499S | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.144); catalogued as COSV99441045; called by muse, mutect2, varscan2
- TMEM80 | c.376G>A p.A126T (on ENST00000526170 / NM_001276274.1; = p.A188T on NM_174940.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.917); catalogued as rs1204882699, COSV100585314; called by muse, mutect2, varscan2
- TRIM39 | c.1166C>T p.T389I | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0.168); catalogued as COSV64955050; called by muse, mutect2, varscan2
- XIAP | c.1327C>T p.R443C | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.487); catalogued as rs1489246570, COSV100848809, COSV63024795; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZBTB39 | c.464C>T p.P155L | Missense Mutation (SNP) | VAF 84/242 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.026); catalogued as COSV100267908; called by muse, mutect2, varscan2
- ZNF768 | c.328C>T p.Q110* | Nonsense Mutation (SNP) | VAF 64/245 reads (26%) | catalogued as COSV99411364; called by muse, mutect2, varscan2
- CC2D1A | c.1029del p.P345Rfs*89 | Frame Shift Del (DEL) | VAF 11/38 reads (29%) | called by mutect2, pindel, varscan2
- CDYL2 | c.1198del p.Q400Rfs*57 | Frame Shift Del (DEL) | VAF 37/224 reads (17%) | called by pindel, varscan2
- EPHA2 | c.1622dup p.A542Gfs*54 | Frame Shift Ins (INS) | VAF 7/40 reads (18%) | called by mutect2, pindel, varscan2
- KMT2B | c.1656del p.K553Nfs*52 | Frame Shift Del (DEL) | VAF 5/26 reads (19%) | called by mutect2, pindel, varscan2
- ADAMTS18 | c.1473G>T p.A491= | Silent (SNP) | VAF 64/317 reads (20%) | catalogued as COSV51400093; called by muse, mutect2, varscan2
- ADGRV1 | c.15456T>C p.P5152= | Silent (SNP) | VAF 99/380 reads (26%) | catalogued as COSV101315514; called by muse, mutect2, varscan2
- ALPK3 | c.1588C>A p.R530= | Silent (SNP) | VAF 28/80 reads (35%) | catalogued as COSV99360213; called by muse, mutect2, varscan2
- CTNNA2 | c.1110T>C p.T370= | Silent (SNP) | VAF 59/240 reads (25%) | catalogued as rs774544806, COSV100559515, COSV58189784; called by muse, mutect2, varscan2
- DCAF12L1 | c.672G>A p.P224= | Silent (SNP) | VAF 34/71 reads (48%) | catalogued as rs770105970, COSV64421435; called by muse, mutect2, varscan2
- FSHR | c.1413C>A p.I471= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV100436593; called by muse, mutect2, varscan2
- GPR45 | c.552G>T p.L184= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV99306684; called by muse, mutect2, varscan2
- GRIN2B | c.3075C>T p.I1025= | Silent (SNP) | VAF 20/86 reads (23%) | catalogued as COSV101662916; called by muse, mutect2, varscan2
- H2BC9 | c.93A>G p.K31= | Silent (SNP) | VAF 64/288 reads (22%) | catalogued as COSV99769022; called by muse, mutect2, varscan2
- MBIP | c.552T>C p.N184= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as rs1187301320, COSV100576710; called by muse, mutect2, varscan2
- PCDHA2 | c.2061G>T p.A687= | Silent (SNP) | VAF 55/262 reads (21%) | catalogued as COSV100973591, COSV65364400; called by muse, mutect2, varscan2
- PLXNA4 | c.726C>A p.I242= | Silent (SNP) | VAF 21/112 reads (19%) | catalogued as COSV58137566, COSV58154570; called by muse, mutect2, varscan2
- PTK2 | c.2862G>A p.V954= | Silent (SNP) | VAF 22/109 reads (20%) | catalogued as COSV100569413; called by muse, mutect2, varscan2
- RMC1 | c.736C>T p.L246= | Silent (SNP) | VAF 31/137 reads (23%) | catalogued as COSV99339893; called by muse, mutect2, varscan2
- TMEM179B | c.585G>A p.R195= | Silent (SNP) | VAF 77/316 reads (24%) | catalogued as rs1565194249, COSV53671345; called by muse, mutect2, varscan2
- ZNF222 | c.1002C>G p.V334= | Silent (SNP) | VAF 50/251 reads (20%) | catalogued as COSV99496135; called by muse, mutect2, varscan2
- ZNF687 | c.1983G>A p.P661= | Silent (SNP) | VAF 29/122 reads (24%) | catalogued as rs777443857, COSV99649308; called by muse, mutect2, varscan2
